Gene-level copy-number profile of tumor specimen ALCH-B2RE-TTP1-A from ALCHEMIST case ALCH-B2RE, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 58.3 years (21,312 days).
Specimen ALCH-B2RE-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 62560870-503d-4c08-a02f-fb0e9c7678a2.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B2RE-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,230 have no estimate.
https://portal.gdc.cancer.gov/files/1ee07130-daa1-469d-afbc-372b999d08f6

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 37; copy number 1: 6,646; copy number 2: 50,123; copy number 3: 718; copy number 4: 530; copy number 5: 147; copy number 6: 88; copy number 8: 50; copy number 9: 5; copy number 10: 9; copy number 11: 33; copy number 13: 7.

Homozygous deletions (total copy number 0; autosomes only): 37 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:5,123,880–5,185,647, 1 gene (within-gene range 0–2): INSL6.
- chr17:17,494,437–17,496,395, 1 gene: RASD1.
- chr20:26,135,983–26,251,546, 4 genes: AL121904.2, MIR663AHG, AL121904.1, MIR663A.
- chr21:7,744,962–8,701,562, 29 genes: SMIM11B, FAM243B, SMIM34B, KCNE1B, CU633980.1, FP671120.5, FP671120.4, MIR6724-1, FP671120.1, MIR3648-1, FP671120.2, FP671120.6, RNA5-8SN2, MIR6724-2, FP671120.3, FP671120.7, 5_8S_rRNA, FP236383.3, MIR6724-3, FP236383.1, FP236383.4, RNA5-8SN3, MIR6724-4, FP236383.2, FP236383.5, RNA5-8SN1, RPSAP68, CR381572.2, CR381572.1.
- chr21:13,038,160–13,067,033, 2 genes: ANKRD30BP2, RNU6-614P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 339 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:58,198–1,345,099, 48 genes, copy number 5–8: AC113430.1, PLEKHG4B, Y_RNA, LRRC14B, AC021087.4, CCDC127, AC021087.3, SDHA, AC021087.5, AC021087.1, PDCD6, PDCD6-AHRR, AC021087.2, AHRR, AC010442.1, AC010442.2, EXOC3-AS1, EXOC3, PP7080, SLC9A3, SLC9A3-AS1, AC106772.2, MIR4456, AC106772.1, CEP72, TPPP, AC026740.1, ZDHHC11B, BRD9P2, ZDHHC11, SPCS2P3, BRD9, TRIP13, AC122719.3, AC122719.1, AC122719.2, AC116351.1, AC116351.2, NKD2, SLC12A7, MIR4635, CTD-3080P12.3, SLC6A19, SLC6A18, AC114291.1, TERT, MIR4457, CLPTM1L.
- chr5:9,621,377–10,478,145, 30 genes, copy number 5–6 (within-gene range 1–6): AC026787.1, TAS2R1, LINC02112, RNA5SP177, AC091838.1, LINC02221, AC091905.2, AC091905.3, AC091905.1, AC091905.4, AC034229.1, AC034229.6, AC034229.5, AC034229.2, AC034229.3, AC034229.4, ATPSCKMT, AC012640.1, CCT5, AC012640.4, AC012640.3, CMBL, Y_RNA, Y_RNA, AC012640.5, AC012640.2, MARCHF6, ROPN1L-AS1, ROPN1L, MIR6131.
- chr11:86,649–207,428, 9 genes, copy number 5 (within-gene range 2–5): OR4F2P, AC069287.1, CICP23, LINC01001, AC069287.3, RNU6-447P, BET1L, SCGB1C1, ODF3.
- chr11:823,634–832,883, 2 genes, copy number 8 (within-gene range 2–8): AP006621.1, CRACR2B.
- chr12:68,332,888–69,460,724, 36 genes, copy number 8–13: LINC02384, AC022511.1, AC008033.3, AC008033.1, AC008033.2, RPSAP12, Metazoa_SRP, RAP1B, RPL10P12, SNORA70G, ATP5PDP4, AC090061.1, RPL7P42, NUP107, KRT8P39, SLC35E3, AC025423.3, MDM2, AC025423.1, AC025423.4, AC025423.2, CPM, RNU7-4P, AC025423.5, PRELID2P1, AC127894.1, CPSF6, MIR1279, C1GALT1P1, AC020656.2, LYZ, AC020656.1, YEATS4, RN7SL804P, RPS26P45, LINC02373.
- chr17:50,475,819–50,555,852, 7 genes, copy number 5: AC021491.4, RSAD1, AC021491.1, MYCBPAP, AC021491.2, EPN3, SPATA20.
- chr17:51,260,546–52,160,017, 8 genes, copy number 6: UTP18, LINC02071, AC005823.2, AC005823.1, LINC02073, RPL7P48, CA10, AC002090.1.
- chr17:61,865,367–63,427,699, 45 genes, copy number 5–11 (within-gene range 2–11): INTS2, Y_RNA, MED13, AC018628.1, RN7SL800P, AC018628.2, Y_RNA, Y_RNA, POLRMTP1, AC053481.3, AC053481.4, TBC1D3P2, AC053481.2, AC053481.1, EFCAB3, AC008026.2, RNU7-52P, RPS23P7, METTL2A, TLK2, AC008026.1, AC008026.3, AC080038.2, AC080038.1, MRC2, Y_RNA, AC080038.3, RNU6-446P, AC005821.1, MARCHF10, AC005821.2, MARCHF10-DT, PRELID3BP3, AC005972.3, MIR633, TRMT112P3, AC005972.1, AC005972.2, TANC2, AC006270.2, AC006270.1, DNAJB6P8, AC015923.1, AC005828.2, AC005828.7.
- chr17:64,039,142–66,810,743, 65 genes, copy number 6–10 (within-gene range 4–10) (broad region; genes not listed).
- chr17:67,070,444–68,763,882, 54 genes, copy number 5: HELZ, AC007448.3, RPL36AP48, AC007448.5, AC007448.4, RNA5SP447, AC007448.1, AC007448.2, PSMD12, PITPNC1, Y_RNA, RN7SL756P, MIR548AA2, MIR548D2, AC110921.1, AC079331.2, AC079331.1, AC079331.3, NOL11, SNORA38B, RPSAP67, RPL17P41, BPTF, AC134407.1, AC134407.2, AC134407.3, RN7SL622P, C17orf58, KPNA2, FBXO36P1, AC145343.1, LINC00674, LRRC37A16P, AC005332.6, AC005332.3, AC005332.5, SH3GL1P3, RDM1P3, AC005332.7, AC005332.2, ARHGAP27P2, AC005332.4, AMZ2, AC005332.1, ARSG, SLC16A6, AC007780.1, WIPI1, MIR635, PRKAR1A, FAM20A, AC079210.1, LINC01482, AC011591.2.
- chr17:73,334,384–74,623,738, 30 genes, copy number 5: SDK2, AC124804.1, AC032019.1, AC032019.2, AC125421.1, LINC00469, LINC02092, AC125421.2, AC137735.1, LINC02074, RPL38, MGC16275, TTYH2, AC100786.1, DNAI2, AC103809.1, KIF19, BTBD17, GPR142, RNA5SP448, GPRC5C, CD300A, CD300LB, CD300C, AC079325.1, CD300H, CD300LD, C17orf77, AC064805.1, CD300E.
- chr19:589,881–617,159, 1 gene, copy number 5 (within-gene range 1–5): HCN2.
- chr19:617,221–633,537, 1 gene, copy number 5: POLRMT.
- chr19:1,248,553–1,274,880, 3 genes, copy number 5: MIDN, CIRBP, CIRBP-AS1.

Autosomal genes at a single copy (total copy number 1): 6,646. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
